Somatic mutation profile of tumor specimen MP2PRT-PAUVJI-TMP1-A (aliquot MP2PRT-PAUVJI-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAUVJI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.3 years (3,394 days).
Specimen MP2PRT-PAUVJI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb6e6346-9b86-4d90-a7de-79f2b3c21fe2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUVJI-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUVJI-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aeb71b3f-d606-45ec-bb09-ba5e9c5aa965

The open-access MAF lists 29 somatic variants for this specimen: 22 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 18, Silent 7, Nonsense Mutation 2, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS3 | c.2861G>A p.R954H | Missense Mutation (SNP) | VAF 124/343 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs377294345, COSV99712423; called by muse, mutect2, varscan2
- GABRA4 | c.1132C>T p.Q378* | Nonsense Mutation (SNP) | VAF 84/229 reads (37%) | catalogued as COSV51932590; called by muse, mutect2, varscan2
- KANK4 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 59/390 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376267940; called by muse, mutect2, varscan2
- KIF25 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 161/405 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as rs775983046, COSV63027690; called by muse, mutect2, varscan2
- LNX2 | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 35/442 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs555322411; called by muse, mutect2
- LRRTM4 | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 47/550 reads (9%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.06); catalogued as COSV69153795; called by muse, mutect2
- PCDHB7 | c.1589G>A p.R530H | Missense Mutation (SNP) | VAF 105/873 reads (12%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.013); catalogued as COSV50757426; called by muse, mutect2, varscan2
- PODN | c.799G>A p.V267I (on ENST00000395871; = p.V219I on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/566 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.163); catalogued as COSV57013455; called by muse, mutect2
- RETREG3 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 103/254 reads (41%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as rs757460358; called by muse, mutect2, varscan2
- RPRD2 | c.4243C>T p.R1415W | Missense Mutation (SNP) | VAF 57/459 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs773186260, COSV100954948; called by muse, mutect2, varscan2
- SPHKAP | c.2159C>T p.T720M | Missense Mutation (SNP) | VAF 148/373 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779285113; called by muse, mutect2, varscan2
- DHX37 | c.1098C>A p.Y366* | Nonsense Mutation (SNP) | VAF 31/358 reads (9%) | called by muse, mutect2
- FIGN | c.1652C>A p.A551D | Missense Mutation (SNP) | VAF 130/407 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- IGHV1-69 | chr14:106714674 del ACACTGTGTCTCTCGCACAGT | Missense Mutation (DEL) | VAF 23/39 reads (59%) | called by mutect2, varscan2
- IGLV4-69 | c.355_359delinsCT p.I119del | In Frame Del (DEL) | VAF 66/106 reads (62%) | called by pindel, varscan2*
- KIFC2 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 70/527 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MYO3B | c.2338C>T p.L780F | Missense Mutation (SNP) | VAF 72/318 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- NPHP4 | c.502C>G p.Q168E | Missense Mutation (SNP) | VAF 22/490 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.006); called by muse, mutect2
- PHF6 | c.959G>T p.G320V | Missense Mutation (SNP) | VAF 26/200 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ROBO2 | c.1544del p.N515Tfs*4 | Frame Shift Del (DEL) | VAF 103/317 reads (32%) | called by mutect2, pindel, varscan2
- SYNPO2 | c.2611A>G p.R871G | Missense Mutation (SNP) | VAF 34/430 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.044); called by muse, mutect2
- TMTC2 | c.527G>T p.G176V | Missense Mutation (SNP) | VAF 58/367 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CFAP91 | c.2133C>G p.V711= | Silent (SNP) | VAF 11/216 reads (5%) | called by muse, mutect2
- DIPK2B | c.1290C>T p.N430= | Silent (SNP) | VAF 104/160 reads (65%) | catalogued as rs1291286010; called by muse, mutect2, varscan2
- HMX1 | c.63C>T p.I21= | Silent (SNP) | VAF 76/700 reads (11%) | called by muse, mutect2
- OR6K3 | c.96A>G p.G32= (on ENST00000368146; = p.G16= on NM_001005327.2) | Silent (SNP) | VAF 42/324 reads (13%) | catalogued as rs529098297; called by muse, mutect2
- SPATA22 | c.60G>A p.P20= | Silent (SNP) | VAF 17/176 reads (10%) | catalogued as rs1439716313; called by muse, mutect2, varscan2
- SPPL2C | c.1875G>A p.L625= | Silent (SNP) | VAF 80/704 reads (11%) | called by muse, mutect2, varscan2
- ZNF610 | c.1242C>T p.Y414= | Silent (SNP) | VAF 36/466 reads (8%) | called by muse, mutect2
